Surgical pathology report (de-identified scan), TCGA case TCGA-S8-A6BW, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-S8-A6BW-01A (Primary Tumor).

[page 1 of 3]
Clinical Information:

year male with history of dysphagia and PET positive mass.

Operative Procedure:

Ivor Lewis esophagectomy

Specimen Received:

- A: Stomach margin (FS)
- B: Esophagus
- C: Esophageal margin (FS)
- D: Subcarinal lymph node
- E: Portal lymph node

Final Pathologic Diagnosis:

A. Stomach, margin, excision:

Negative for malignancy.

Fifteen benign lymph nodes (0/15).

Granuloma consistent with the history of sarcoidosis.

B. Esophagus, Ivor-Lewis esophagectomy:

Specimen: Esophagus

Procedure: Ivor-Lewis esophagectomy

Tumor site: Esophagus, not otherwise specified

Relationship of tumor to esophagogastric junction:

Tumor is entirely located above the esophagogastric junction

Distance of tumor center from esophagogastric junction cannot be assessed

Tumor size: 5.2 x 4.3 x 2.1 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Well differentiated

Microscopic tumor extension: Tumor invades into the muscularis propria

Margins:

Proximal margin: Uninvolved by invasive carcinoma

Distal margin: Uninvolved by invasive carcinoma

Circumferential (adventitial) margin: Uninvolved by invasive carcinoma

If all margins uninvolved by invasive carcinoma,

distance of invasive carcinoma from closest margin:

<0.1 cm

Specify margin: Circumferential
(adventitial) margin

Treatment effect: None

Lymph-vascular invasion: Not identified

ICD-O-3
Carcinoma, squamous
cell NOS 8070/3
Site Esophagus NOS
C15.9
JPD 5/24/13

[page 2 of 3]
Perineural invasion: Not identified

Pathologic staging (pTNM):

TNM descriptors: None known
Primary tumor (pT): pT2
Regional lymph nodes (pN): pN0
Number examined: 22 also see parts A, D, and E
Number involved: 0
Distant metastasis (pM): pMX

Additional pathologic findings: Granuloma consistent with the history of sarcoidosis.

C. Esophagus, margin, resection:

Negative for malignancy.
Frozen section diagnosis confirmed.

D. Lymph node, subcarinal, excision:

One benign lymph node (0/1).
Granuloma consistent with the history of sarcoidosis.

E. Lymph node, portal, excision:

One benign lymph node (0/1).
Granuloma consistent with the history of sarcoidosis.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSA1&A2: Stomach margin:
Negative for tumor.
F/S TAT: 14.5 mins.

FSC: Esophageal margin:

Negative for tumor.
F/S TAT: 16 mins.

Gross Description:

Received are five containers, all labeled with the patient's name

Part A is received fresh for frozen section and additionally labeled "stomach margin" and consists of an 8.2 x 5.2 x 4.7 cm partial stomach resection. There is a moderate amount of attached fat. There is also 0.9 cm of distal esophagus attached. The esophageal mucosa is tan-pink and wrinkled. The gastric mucosa is tan with the normal folds.

Representative sections are submitted as follows:

A1 residual tissue from frozen section A1;

[page 3 of 3]
- A2-3 residual frozen section A2;
- A4-5 representative sections of GE junction;
- A6 one whole probable lymph node trisected;
- A7-9 probable lymph nodes.

Part B is received in formalin additionally labeled "esophagus" and consists of a 9.7 cm in length segment of esophagus with moderate attached amount of fat. The specimen is not oriented. The specimen is previously opened to reveal a 5.2 x 4.3 cm tan centrally ulcerated mass with raised, irregular well delineated borders. The mass comes to within 1.6 cm of the mucosal margin and 4.9 cm of the opposing mucosal margin. The mass on sectioning is tan, firm and homogeneous with a thickness of 2.1 cm. The mass involves the muscularis propria and possibly extends to the subjacent fat and abuts the inked deep margin. The uninvolved esophageal mucosa is tan-pink and wrinkled. Search of the adjacent fat reveals a 2.9 x 2.3 x 1.5 cm lymph node and additional multiple probable lymph nodes.

Representative sections are submitted as follows:

- B1-4 representative sections of tumor;
- B5-6 normal esophagus;
- B7 representative sections of lymph node;
- B8 multiple probable lymph nodes.

Part C is received fresh for frozen section and additionally labeled "esophageal margin" and consists of three portions of pink-tan soft tissue. Residual sections are submitted in cassettes C1 and C2.

Part D is received in formalin and additionally labeled "subcarinal lymph node" and consists of two portions of tan-brown irregular soft tissue, one with dimensions of 1.7 x 0.7 x 0.3 cm and the second with dimensions of 1.9 x 0.5 x 0.2 cm. The specimen is submitted in toto in cassette D1.

Part E is received in formalin and additionally labeled "portal lymph node" and consists of a portion of pink-tan to brown irregular soft tissue with dimensions of 3.1 x 1.4 x 1.2 cm. The specimen is step sectioned to reveal a pink-tan cut surface. Representative sections are submitted in cassette E1.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: DOB: (Age) Gender: M

Source: NCI Genomic Data Commons file db158fa8-c4c4-4d7c-b1f7-2769123a18e4 (TCGA-S8-A6BW.820EE304-5074-4DDA-A33A-2560184666F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).